Somatic mutation profile of tumor specimen TCGA-19-5950-01A (aliquot TCGA-19-5950-01A-11D-1696-08) from TCGA case TCGA-19-5950, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,244 days).
Specimen TCGA-19-5950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05c679a8-1472-48ed-83d9-88986e2ab27b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-5950-10A (Blood Derived Normal), aliquot TCGA-19-5950-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dae418b-0691-429a-9f78-56b52c812c2e

The open-access MAF lists 57 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 10, Splice Site 2, Nonsense Mutation 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LSM14A | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 81/236 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1370603291, COSV70884805; called by muse, mutect2, varscan2
- ABCG2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1272411168, COSV52948003; called by muse, mutect2, varscan2
- ACAN | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370865297; called by muse, mutect2, varscan2
- ANKRD12 | c.5638C>T p.P1880S | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50837723; called by muse, mutect2, varscan2
- ATM | c.5258A>G p.Y1753C | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs777481236, COSV53762375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD93 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55667509; called by muse, mutect2
- CDCA2 | c.1220C>A p.S407Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57947704; called by muse, mutect2, varscan2
- COL12A1 | c.986G>T p.S329I | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59403061; called by muse, mutect2, varscan2
- CSMD1 | c.5176G>A p.G1726S (on ENST00000520002; = p.G1725S on NM_033225.6) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59358266; called by muse, mutect2
- DGAT1 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs782733856; called by pindel, varscan2
- DMD | c.4499C>T p.S1500L | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV63748023; called by muse, mutect2, varscan2
- DNAH11 | c.13262C>T p.P4421L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs780579730, COSV60970576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.074); catalogued as rs141072655; called by muse, mutect2, varscan2
- DOP1A | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 47/113 reads (42%) | catalogued as COSV52714800; called by muse, mutect2, varscan2
- EMB | c.878-1G>A p.X293_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | catalogued as COSV57483605; called by muse, mutect2
- EPHA8 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs768374859, COSV51263672; called by muse, mutect2, varscan2
- ERC2 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs200184138, COSV55666387; called by muse, mutect2, varscan2
- GRIK3 | c.272G>C p.S91T | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV66144023; called by muse, mutect2, varscan2
- IRF5 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV50857968; called by muse, mutect2, varscan2
- KLHL13 | c.1105T>A p.W369R | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53251230; called by muse, mutect2, varscan2
- MAGEA8 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1557371039, COSV54064054; called by muse, mutect2, varscan2
- MSR1 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs752948497, COSV50521733; called by muse, mutect2, varscan2
- NTN4 | c.1418A>C p.H473P | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.177); catalogued as COSV59222375; called by muse, mutect2, varscan2
- OCLN | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757935966, COSV62285799; called by muse, mutect2, varscan2
- OR2A12 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as rs770997909, COSV68821180; called by muse, mutect2, varscan2
- OR5AN1 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.98); PolyPhen benign (0.033); catalogued as rs917770378, COSV58322564; called by muse, mutect2, varscan2
- P2RY10 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as rs200750596, COSV50682648; called by muse, mutect2, varscan2
- PKHD1L1 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs774262365, COSV65748990; called by muse, mutect2, varscan2
- PNCK | c.284G>A p.G95D (on ENST00000340888 / NM_001366975.1; = p.G178D on NM_001039582.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61744910; called by muse, mutect2, varscan2
- PPP1R9A | c.2269T>C p.Y757H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as rs1468897369, COSV56903893; called by muse, mutect2, varscan2
- PRDM9 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as rs747179714, COSV57010662; called by muse, varscan2
- PREP | c.1070G>A p.R357Q (on ENST00000369110; = p.R423Q on NM_002726.5) | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs141737006; called by muse, mutect2, varscan2
- RAB39B | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs782746706, COSV65624999; called by muse, mutect2, varscan2
- RAB9B | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV54588067; called by muse, mutect2, varscan2
- RBL1 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs746022907, COSV60331923; called by muse, mutect2, varscan2
- REM1 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV52429319; called by muse, mutect2, varscan2
- RHOXF1 | c.398+2T>A p.X133_splice | Splice Site (SNP) | VAF 41/101 reads (41%) | catalogued as COSV54295755; called by muse, mutect2, varscan2
- SDC1 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV54340980; called by muse, mutect2, varscan2
- SLC33A1 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63947558; called by muse, mutect2, varscan2
- SORBS1 | c.93A>T p.L31F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV53362342; called by muse, mutect2, varscan2
- TIMELESS | c.1385G>A p.R462K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV57513852; called by muse, mutect2, varscan2
- TLR7 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs200329031, COSV66125028; called by muse, mutect2, varscan2
- TMEM229B | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.115); catalogued as COSV62538978; called by muse, mutect2, varscan2
- TRAM1L1 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV60291446, COSV60292856; called by muse, mutect2, varscan2
- WFIKKN2 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs372115241; called by muse, mutect2, varscan2
- IGHV2-26 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ARSL | c.285G>A p.T95= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1450519948, COSV66965074; called by muse, mutect2, varscan2
- CHGB | c.588C>T p.N196= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as rs149359798, COSV66760391, COSV66760799; called by muse, mutect2, varscan2
- FBP2 | c.666G>A p.A222= | Silent (SNP) | VAF 86/177 reads (49%) | catalogued as rs367608023; called by muse, mutect2, varscan2
- FOXA1 | c.474C>T p.D158= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV51648194; called by muse, mutect2, varscan2
- ITIH2 | c.744C>T p.H248= | Silent (SNP) | VAF 53/84 reads (63%) | catalogued as rs775362609, COSV64434454; called by muse, mutect2, varscan2
- KCNC2 | c.543C>T p.D181= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV54363492; called by muse, mutect2
- LRRK1 | c.2415C>T p.S805= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV52621934; called by muse, mutect2, varscan2
- MOB3B | c.333G>A p.A111= | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as rs753880222, COSV51785329; called by muse, mutect2, varscan2
- RPA4 | c.609C>T p.D203= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs1259456879, COSV100230038, COSV61284418; called by muse, mutect2, varscan2
- TSSK3 | c.21C>A p.S7= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as COSV61982782; called by muse, mutect2, varscan2
- ZNF385B | c.*1C>T | 3'UTR (SNP) | VAF 28/61 reads (46%) | catalogued as rs368089964, COSV61177912; called by muse, mutect2, varscan2
